Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NI, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NI-01A (Primary Tumor).

[page 1 of 3]
ICD-O.3

Adenocarcinoma NOS
8140/3

Site ^{OSCE} Esophagus, distal
C15.5

^{path} third
Gastroesophageal junction
C16.0

QJ 11/7/14

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

Source of specimen: Thoracic esophagus.

67-year-old male with one-year history of dysphagia, treated with over-the-counter medications, then multiple PPIs. Barium swallow, then EGD, positive for cancer. No radiation or chemotherapy. Clinical Diagnosis: Esophageal cancer. Operative Procedure: Transhiatal esophagectomy.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR: !

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

1. "Thoracic esophagus." Received in formalin in a medium container is a 9 x 4.5 cm distal portion of esophagus, in continuity with 7 x 6 cm portion of stomach. There is a 6.5 x 5 x 1.1 cm tan-brown, ulcerative tumor with rolled edge at the GE junction. The tumor involves circumferentially 80% of the organ, 6 cm from the esophageal surgical margin and 3.2 cm from the distal gastric surgical margin. The tumor invades through the muscular layer and approaches the serosal surface. The proximal half of the esophagus and stomach are grossly unremarkable. The serosal surface is inked black, serially sectioned and sampled.
- 1A. Tumor at esophageal edge.
- 1B-1C. Tumor.
- 1D. Tumor at gastric edge.
- 1E. Normal esophagus and stomach.
- 1F-1G. Largest lymph node, 2.2 x 1.7 x 1.3 cm.
- 1H. One lymph node, bisected.
- 1I. Two lymph nodes, inked yellow or orange, bisected.
- 1J. Two lymph nodes, inked yellow or orange, bisected.
- 1K. Possible lymph nodes.
- 1L. Possible lymph nodes.
2. "Esophageal margin." A ring of esophagus, 1.2 cm in diameter, 0.7 cm in length. Margin inked.
3. "Lower left paraesophageal lymph node." Received in formalin in a small container is a 2.7 x 1.9 x 0.6 cm portion of adipose tissue. Serially sectioned.
- 3A. Lymph nodes.
- 3B. Remaining adipose tissue.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma:

If adenocarcinoma, it is arising in: Arising at GE junction, not otherwise specified.

Depth of invasion: Adventitia.

Number of positive lymph nodes: 4/19.

Extranodal metastasis: Unknown.

Specify site: _

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 4
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Pattern of invasion: Infiltrative.
Esophageal and gastric resection margins involved: No.
Deep resection margin involved: No.
TNM classification: T3 N1 MX

PROCEDURE:

VERIFIED BY:

1. Esophagus, excision: Transmurally invasive, poorly-differentiated adenocarcinoma with metastasis to four of nineteen lymph nodes. Surgical margins free. No Barrett's mucosa identified. Please see template.
2. Esophageal margin, excision: No significant abnormality.
3. Lower left periesophageal lymph node, excision: Benign fibroadipose tissue, no lymph node present.

I, _____ signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 1d7d50f2-9b0e-4444-86e3-30718c33cf53 (TCGA-L5-A8NI.72D3550D-D524-4965-8C7A-F10060DEA06A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).